Gene-level copy-number profile of tumor specimen ALCH-B2QS-TTP1-A from ALCHEMIST case ALCH-B2QS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 46.8 years (17,089 days).
Specimen ALCH-B2QS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3906e9a5-dae3-4016-9db7-d6e235e28769.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2QS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/0d706f79-94ad-4b8f-8ba9-3784ca743745

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 461; copy number 1: 21,159; copy number 2: 33,302; copy number 3: 2,874; copy number 4: 853; copy number 5: 170; copy number 6: 12; copy number 7: 1; copy number 9: 30; copy number 11: 36; copy number 13: 3.

Homozygous deletions (total copy number 0; autosomes only): 102 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,720,312–15,793,285, 6 genes (within-gene range 0–1): AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1, RPL12P14.
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr2:218,366,665–218,405,941, 5 genes (within-gene range 0–1): CATIP-AS1, SLC11A1, CTDSP1, AC021016.2, MIR26B.
- chr3:30,726,200–30,894,765, 1 gene: GADL1.
- chr5:133,111,055–133,224,413, 3 genes (within-gene range 0–1): AC113410.2, AC010307.2, AC010307.1.
- chr5:133,243,764–133,275,977, 2 genes (within-gene range 0–1): AC010307.3, AC010307.4.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:21,453,802–22,214,672, 23 genes: MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:86,654,547–86,736,072, 2 genes: OPN4, LDB3.
- chr10:103,493,979–103,592,552, 3 genes (within-gene range 0–1): NEURL1, AL121929.1, AL121929.3.
- chr10:103,608,619–103,673,265, 2 genes (within-gene range 0–1): AL121929.2, Y_RNA.
- chr11:134,032,216–134,067,936, 2 genes: LINC02731, AP000911.1.
- chr14:74,239,449–74,262,738, 1 gene: VSX2.
- chr14:102,501,676–102,539,726, 3 genes (within-gene range 0–1): RNU6-244P, ANKRD9, MIR4309.
- chr14:102,582,888–102,583,177, 1 gene: RN7SL546P.
- chr15:20,344,736–20,359,166, 1 gene (within-gene range 0–2): AC026495.1.
- chr15:25,185,631–25,225,284, 22 genes (within-gene range 0–2): SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:15,104,312–15,131,601, 2 genes (within-gene range 0–2): NPIPP1, PKD1P6-NPIPP1.
- chr16:54,239,693–54,292,422, 5 genes: AC007907.1, LINC02169, IRX3, AC018553.2, AC018553.1.
- chr17:59,859,479–59,892,945, 2 genes: TUBD1, NDUFB8P2.
- chr21:37,337,382–37,526,358, 3 genes: AP001437.2, AP001437.1, DYRK1A.
- chr21:43,322,417–43,366,566, 3 genes: LINC00322, LINC01679, AP001046.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 252 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:224,434,660–224,740,554, 3 genes, copy number 6 (within-gene range 4–6): CNIH3, AKR1B1P1, CNIH3-AS2.
- chr1:224,703,272–224,712,849, 1 gene, copy number 6: AL596330.1.
- chr1:246,566,444–246,668,595, 1 gene, copy number 5 (within-gene range 4–5): CNST.
- chr1:246,632,251–247,078,811, 16 genes, copy number 5: AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341, AC113174.1, AC113174.2, AHCTF1, ZNF695, ZNF670-ZNF695, AL512637.2, ZNF670, AL512637.1.
- chr1:248,556,912–248,655,528, 8 genes, copy number 6: OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27.
- chr3:180,989,762–181,836,880, 1 gene, copy number 11 (within-gene range 3–11): SOX2-OT.
- chr3:181,372,732–183,555,706, 43 genes, copy number 5–11: AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1.
- chr3:186,930,325–189,325,304, 30 genes, copy number 9: ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2.
- chr9:12,134–37,269, 4 genes, copy number 5–7: DDX11L5, MIR1302-9HG, MIR1302-9, FAM138C.
- chr17:22,523,111–29,057,216, 142 genes, copy number 5 (broad region; genes not listed).
- chr22:20,338,805–20,354,387, 3 genes, copy number 13 (within-gene range 2–13): FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 18,662. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
